Gene-level copy-number profile of tumor specimen TCGA-12-1093-01A from TCGA case TCGA-12-1093, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,297 days).
Specimen TCGA-12-1093-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8f743fb8-0050-40cb-b1f8-6e277fc123ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1093-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b00ea3ef-c16e-4a9b-9c90-5a7050f9acef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 8,565; copy number 2: 48,232; copy number 3: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-1093-01A-01D-0517-01): tumor purity 0.4, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:101,181,257–102,070,083, 1 gene (within-gene range 0–2): GRIK2.
- chr6:102,078,872–102,079,555, 1 gene: AP002530.1.
- chr11:80,321,620–81,040,236, 6 genes: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
